Somatic mutation profile of tumor specimen TCGA-B8-5158-01A (aliquot TCGA-B8-5158-01A-01D-1421-08) from TCGA case TCGA-B8-5158, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 56.8 years (20,764 days).
Specimen TCGA-B8-5158-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0315af6-57b2-44c9-afd4-33e3daa9fae1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-5158-10A (Blood Derived Normal), aliquot TCGA-B8-5158-10A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db63e68e-74c6-4537-9631-64951523d524

The open-access MAF lists 66 somatic variants for this specimen: 49 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 15, Frame Shift Del 4, Nonsense Mutation 2, Splice Site 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP3 | c.86A>C p.N29T (on ENST00000622464; = p.N65T on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52544595; called by muse, mutect2
- B4GALNT4 | c.278T>C p.M93T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV57324440; called by muse, mutect2
- BCL2A1 | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51213482; called by muse, mutect2
- BIVM-ERCC5 | c.800T>C p.L267P | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57280986; called by muse, mutect2
- BIVM-ERCC5 | c.802A>T p.M268L | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs770268882, COSV57281006; called by muse, mutect2
- BRINP2 | c.225G>T p.M75I | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV64178704; called by muse, mutect2, varscan2
- BSDC1 | c.956T>A p.L319Q | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.045); catalogued as COSV61982555; called by muse, mutect2, varscan2
- CATIP | c.1091T>G p.L364W | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV56823464; called by muse, mutect2, varscan2
- CDK8 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101037042, COSV67421688; called by muse, mutect2, varscan2
- CNTNAP3 | c.3403T>G p.F1135V | Missense Mutation (SNP) | VAF 58/456 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV52670812; called by muse, mutect2, varscan2
- COP1 | c.1342T>C p.Y448H | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV58170923; called by muse, mutect2
- COPA | c.3328A>G p.N1110D | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.703); catalogued as COSV54099110, COSV54105373; called by muse, mutect2, varscan2
- CRYBG1 | c.4578+1G>A p.X1526_splice | Splice Site (SNP) | VAF 22/398 reads (6%) | catalogued as COSV64813163; called by muse, mutect2
- DROSHA | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1390623554, COSV60773246; called by muse, mutect2
- EP300 | c.7079A>G p.E2360G | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs945211430, COSV54337734; called by muse, mutect2, varscan2
- FBLN1 | c.1047G>C p.E349D | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV53050396; called by muse, mutect2, varscan2
- FLG | c.4302C>A p.S1434R | Missense Mutation (SNP) | VAF 52/429 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV64240863; called by muse, mutect2, varscan2
- FSCB | c.917C>A p.A306D | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as COSV61218827; called by muse, mutect2, varscan2
- GRIN1 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as COSV59298316; called by muse, mutect2
- ITPRID1 | c.2005A>G p.K669E | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV60077956; called by muse, mutect2, varscan2
- LAMC2 | c.2355T>G p.Y785* | Nonsense Mutation (SNP) | VAF 15/108 reads (14%) | catalogued as COSV51457481; called by muse, mutect2, varscan2
- LRIG1 | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV56243770; called by muse, mutect2, varscan2
- MACROD2 | c.1223A>C p.K408T (on ENST00000642719; = p.K380T on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV54013359; called by muse, mutect2, varscan2
- MIGA1 | c.1186C>A p.Q396K | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as COSV66224132, COSV66224174; called by muse, mutect2, varscan2
- MYBL2 | c.2049G>T p.Q683H | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs776987820, COSV53831650; called by muse, mutect2, varscan2
- MYH2 | c.5424G>T p.Q1808H | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55442398; called by muse, mutect2, varscan2
- MYO5B | c.2237T>A p.I746N | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53224082; called by muse, mutect2
- NLE1 | c.827A>C p.D276A | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV62604676; called by muse, mutect2
- NMT2 | c.1277A>G p.N426S | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs1157634182, COSV65382578; called by muse, mutect2, varscan2
- PBRM1 | c.814-1G>A p.X272_splice | Splice Site (SNP) | VAF 4/39 reads (10%) | catalogued as COSV56272720, COSV56284896; called by muse, mutect2, varscan2
- PCDHB13 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.014); catalogued as COSV53398626; called by muse, mutect2, varscan2
- PRKD3 | c.2119C>A p.L707I | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52215145; called by muse, mutect2
- PTEN | c.787A>T p.K263* | Nonsense Mutation (SNP) | VAF 16/102 reads (16%) | catalogued as rs1554825254, COSV64298269; called by muse, varscan2
- RIF1 | c.1983T>G p.N661K | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV54619970; called by muse, mutect2, varscan2
- S100A10 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 59/462 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV64291245, COSV64291305; called by muse, mutect2, varscan2
- SPEN | c.5260G>A p.D1754N | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1176124993, COSV65364516; called by muse, mutect2, varscan2
- SPEN | c.9341C>G p.P3114R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV65364520; called by muse, mutect2, varscan2
- SREBF2 | c.1447C>T p.L483F | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV63331740; called by muse, mutect2
- TNKS | c.3616G>A p.G1206R | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60062104; called by muse, mutect2
- TRIM23 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.167); catalogued as COSV51552535, COSV51552823; called by muse, mutect2, varscan2
- VARS2 | c.2440C>T p.L814F | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58913358; called by muse, mutect2
- ZMIZ2 | c.1470C>G p.S490R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as COSV54809493; called by muse, mutect2
- ZNF398 | c.1852T>A p.S618T (on ENST00000475153 / NM_170686.3; = p.S447T on NM_020781.4) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV60065900; called by muse, mutect2, varscan2
- ZNF407 | c.3203A>C p.E1068A | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55260099; called by muse, mutect2, varscan2
- ZNF491 | c.368T>A p.V123E | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.129); catalogued as COSV60058048; called by muse, mutect2, varscan2
- OR2H2 | c.248del p.L83Pfs*31 | Frame Shift Del (DEL) | VAF 27/126 reads (21%) | called by mutect2, varscan2
- PRPF8 | c.466del p.R156Efs*28 | Frame Shift Del (DEL) | VAF 9/79 reads (11%) | called by mutect2, pindel, varscan2
- THRA | c.886_887del p.S296Rfs*5 | Frame Shift Del (DEL) | VAF 12/132 reads (9%) | called by pindel, varscan2
- ZFP64 | c.554del p.S185Tfs*6 | Frame Shift Del (DEL) | VAF 41/279 reads (15%) | called by mutect2, pindel, varscan2
- CFTR | c.1500C>A p.G500= | Silent (SNP) | VAF 30/258 reads (12%) | catalogued as rs762619288, COSV50057629; ClinVar: likely benign; called by muse, mutect2, varscan2
- DIP2C | c.3660C>G p.A1220= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV55145025, COSV55179007; called by muse, mutect2, varscan2
- EPHA10 | c.1674G>T p.G558= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV57625244; called by muse, mutect2, varscan2
- GTF2E1 | c.765C>T p.V255= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as rs1311233082, COSV52205226; called by muse, mutect2, varscan2
- H2AC17 | c.147G>C p.P49= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as COSV58153356; called by muse, mutect2, varscan2
- HDLBP | c.2382C>T p.I794= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs1314480400, COSV60498533; called by muse, mutect2, varscan2
- INSIG2 | c.168G>A p.T56= | Silent (SNP) | VAF 16/261 reads (6%) | catalogued as rs376950162; called by muse, mutect2
- NAF1 | c.1176T>C p.P392= | Silent (SNP) | VAF 28/149 reads (19%) | catalogued as rs1287199403, COSV56804990; called by muse, mutect2, varscan2
- NEO1 | c.4150T>C p.L1384= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV56074467; called by muse, mutect2, varscan2
- NUP88 | c.1962C>T p.L654= | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as COSV52586392; called by muse, mutect2, varscan2
- SBF1 | c.1407A>G p.E469= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV62368754; called by muse, mutect2
- SEPTIN4 | c.513G>T p.R171= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV57897602; called by muse, mutect2, varscan2
- SPEN | c.5259T>C p.P1753= | Silent (SNP) | VAF 23/148 reads (16%) | catalogued as rs766644588, COSV65364511; called by muse, mutect2, varscan2
- TSPAN31 | c.369G>C p.L123= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV57276579; called by muse, mutect2, varscan2
- UBR4 | c.8712A>G p.S2904= | Silent (SNP) | VAF 7/148 reads (5%) | catalogued as COSV64393669; called by muse, mutect2
- AP000769.5 | chr11:65500612 A>G | 5'Flank (SNP) | VAF 19/116 reads (16%) | called by muse, mutect2, varscan2
- VPS11 | chr11:119069501 C>G | 5'Flank (SNP) | VAF 17/99 reads (17%) | catalogued as rs782371702, COSV56186108, COSV56186999; called by muse, mutect2, varscan2
